Gene-level copy-number profile of tumor specimen TCGA-50-5066-02A from TCGA case TCGA-50-5066, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.2 years (26,385 days).
Specimen TCGA-50-5066-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f0d74a66-0d34-41fa-8b88-704c25b079f5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5066-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 407 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f2bb6708-087a-47e0-821b-7b2301950bed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,824; copy number 1: 1,289; copy number 2: 1,900; copy number 3: 17,678; copy number 4: 21,640; copy number 5: 4,775; copy number 6: 6,438; copy number 7: 1,929; copy number 8: 1,156; copy number 9: 257; copy number 10: 76; copy number 11: 531; copy number 12: 217; copy number 14: 63; copy number 15: 136; copy number 16: 203; copy number 17: 47; copy number 25: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5066-02A-11D-2085-01): tumor purity 0.41, ploidy 4.36, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,719,222–61,681,049, 8 genes: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1.
- chr8:26,375,913–26,514,092, 6 genes: SDAD1P1, BNIP3L, AC011726.1, DNAJB6P2, AC011726.2, PNMA2.
- chr8:32,911,493–33,045,445, 5 genes: RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,587 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,041,199–29,181,900, 5 genes, copy number 15: Metazoa_SRP, TMEM200B, AL357500.1, SRSF4, AL357500.2.
- chr1:32,741,830–33,496,507, 29 genes, copy number 9 (within-gene range 5–9): KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20.
- chr1:247,639,630–248,122,882, 33 genes, copy number 15–16 (within-gene range 7–16): AL390860.1, OR3D1P, OR13G1, OR6F1, AC118470.1, OR14A2, OR14K1, OR1C1, OR9H1P, OR14A16, HSD17B7P1, OR6R1P, OR11L1, TRIM58, OR2W3, OR2T8, OR2AJ1, CLK3P2, OR2X1P, OR2L8, OR2AK2, OR2L9P, OR2L1P, Y_RNA, OR2L6P, OR2L5, Y_RNA, OR2L2, Y_RNA, OR2L3, OR2T32P, OR2L13, OR2M1P.
- chr5:58,198–16,936,288, 292 genes, copy number 9–25 (within-gene range 7–25) (broad region; genes not listed).
- chr5:17,065,598–17,670,571, 45 genes, copy number 15: BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22.
- chr5:29,516,005–29,600,868, 2 genes, copy number 12: AC027345.1, UBL5P1.
- chr5:50,603,229–50,603,511, 1 gene, copy number 10: AC112187.2.
- chr7:70,972–5,970,683, 134 genes, copy number 12–14 (broad region; genes not listed).
- chr7:6,161,776–9,189,857, 64 genes, copy number 15 (within-gene range 7–15) (broad region; genes not listed).
- chr8:40,900,016–46,028,892, 83 genes, copy number 9–16 (broad region; genes not listed).
- chr8:46,784,800–46,819,098, 4 genes, copy number 15: AC021451.1, TRIM60P15, AC021451.2, AC021451.3.
- chr8:48,428,143–48,824,062, 10 genes, copy number 9: AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1.
- chr8:49,817,586–86,212,236, 541 genes, copy number 10–11 (broad region; genes not listed).
- chr8:88,032,011–98,294,393, 160 genes, copy number 11–12 (within-gene range 11–20) (broad region; genes not listed).
- chr8:126,474,189–137,105,458, 130 genes, copy number 9 (broad region; genes not listed).
- chr10:70,815,948–72,013,558, 18 genes, copy number 9: SGPL1, PCBD1, AC073176.2, AC073176.1, LINC02622, UNC5B, UNC5B-AS1, SLC29A3, AL359183.1, CDH23, CDH23-AS1, C10orf105, VSIR, MIR7152, PSAP, RNU7-38P, AC073370.1, CHST3.
- chr17:36,103,827–36,177,510, 3 genes, copy number 14: CCL4, RN7SL301P, AC243829.2.
- chr21:21,933,315–22,154,299, 5 genes, copy number 15: AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1.
- chr21:38,380,027–38,956,467, 11 genes, copy number 9: ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64.
- chr21:39,342,315–39,929,397, 17 genes, copy number 10 (within-gene range 5–10): HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4.

Autosomal genes at a single copy (total copy number 1): 153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
